Somatic mutation profile of tumor specimen TCGA-FE-A3PA-01A (aliquot TCGA-FE-A3PA-01A-12D-A21Z-08) from TCGA case TCGA-FE-A3PA, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 16.6 years (6,068 days).
Specimen TCGA-FE-A3PA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50315f64-0191-49ed-915a-da78bf120152.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FE-A3PA-10A (Blood Derived Normal), aliquot TCGA-FE-A3PA-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b65c983-ba0d-426b-8de0-76284631146c

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUL2 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as rs190367917; called by muse, mutect2, varscan2
- PCDHB11 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 77/202 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.275); catalogued as rs1554285369, COSV100696889, COSV61314349; called by muse, mutect2, varscan2
- MEN1 | c.1503G>A p.K501= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1229427600, COSV99580196; called by muse, mutect2
